Somatic mutation profile of tumor specimen TCGA-56-8308-01A (aliquot TCGA-56-8308-01A-11D-2293-08) from TCGA case TCGA-56-8308, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 79.8 years (29,139 days).
Specimen TCGA-56-8308-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e562a61-c409-4412-b692-cefefbf87630.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8308-10A (Blood Derived Normal), aliquot TCGA-56-8308-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05840a85-013b-4269-8ce9-5d73f09f5951

The open-access MAF lists 388 somatic variants for this specimen: 293 protein-altering or splice-affecting, 89 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 255, Silent 89, Nonsense Mutation 16, Frame Shift Del 7, Splice Site 6, Splice Region 5, Frame Shift Ins 3, RNA 3, Intron 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064795691, COSV52678014, COSV52747111, COSV52839912, COSV53772942; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA10 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99287798; called by muse, mutect2, varscan2
- ABCA9 | c.4321G>C p.V1441L | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV100382567, COSV60632274; called by muse, mutect2, varscan2
- ABCG8 | c.194T>A p.F65Y | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99699402; called by muse, mutect2, varscan2
- ADARB2 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101186580; called by muse, mutect2, varscan2
- ADGRB3 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV104424271, COSV65415526; called by muse, mutect2, varscan2
- ADGRB3 | c.3541C>A p.H1181N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV53260952, COSV99483344; called by muse, mutect2, varscan2
- ADGRG5 | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100446323, COSV61082872; called by muse, mutect2, varscan2
- AKR1B15 | c.783G>C p.K261N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV101423347; called by muse, mutect2, varscan2
- AKR1D1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV54341157, COSV99652795; called by muse, mutect2
- ALDH1A2 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.122); catalogued as COSV99990309; called by muse, mutect2, varscan2
- ALDH1A2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.174); catalogued as rs1283761840, COSV51078204; called by muse, mutect2, varscan2
- ALPK3 | c.684C>A p.S228R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99360140; called by muse, varscan2
- ARHGEF2 | c.290C>T p.A97V (on ENST00000361247 / NM_001162383.2; = p.A70V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58106770; called by muse, mutect2, varscan2
- ASTE1 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.248); catalogued as COSV53908589, COSV99393613; called by muse, mutect2, varscan2
- ATG16L1 | c.1259A>G p.N420S (on ENST00000392017 / NM_030803.7; = p.N401S on NM_017974.4) | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.676); catalogued as rs1242949611, COSV100731256; called by muse, mutect2, varscan2
- ATP13A5 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.033); catalogued as COSV100664694; called by muse, mutect2, varscan2
- ATP9B | c.1025C>A p.A342E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100302787; called by muse, mutect2, varscan2
- BAHD1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV101346711; called by muse, mutect2, varscan2
- BCCIP | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV99501296; called by muse, mutect2, varscan2
- BRAF | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV56122422, COSV56190066; called by muse, mutect2, varscan2
- BRINP1 | c.1214C>A p.T405N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs1304120605; called by muse, mutect2, varscan2
- C6 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV99666447; called by muse, mutect2, varscan2
- CALM3 | c.435G>C p.M145I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.094); catalogued as COSV52194566; called by muse, mutect2, varscan2
- CCDC172 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100319633; called by muse, mutect2, varscan2
- CCDC197 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV100113588; called by muse, mutect2, varscan2
- CCDC50 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101165242; called by muse, mutect2, varscan2
- CCDC9B | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as rs558204056, COSV66875654; called by muse, mutect2, varscan2
- CD1E | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100936901; called by muse, mutect2, varscan2
- CDKL2 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs1385759335, COSV100276710; called by muse, mutect2, varscan2
- CENPE | c.5131G>A p.E1711K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV99476874; called by muse, mutect2, varscan2
- CENPJ | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67882885; called by muse, mutect2, varscan2
- CEP112 | c.386C>A p.T129K | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV67144426; called by muse, mutect2, varscan2
- CEP152 | c.2069G>T p.R690L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs778066207, COSV100358461, COSV57860852; called by muse, mutect2, varscan2
- CHRM3 | c.382T>A p.Y128N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697382; called by muse, mutect2, varscan2
- CHRNA3 | c.267+2T>A p.X89_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100467804; called by muse, mutect2, varscan2
- CHRNA7 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100180721; called by muse, mutect2, varscan2
- CHRNA7 | c.544A>T p.M182L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as COSV100180722; called by muse, mutect2, varscan2
- CNTN3 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99723143; called by muse, mutect2
- CNTN3 | c.319G>T p.G107* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99723145; called by muse, mutect2
- CNTNAP5 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.506); catalogued as rs766267486, COSV101442999; called by muse, mutect2, varscan2
- COL12A1 | c.1931C>G p.T644S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.466); catalogued as COSV100485333; called by muse, mutect2, varscan2
- COL6A3 | c.4985T>C p.V1662A | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs1333302966, COSV99796106; called by muse, mutect2, varscan2
- CR1 | c.4762A>G p.T1588A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1433020893, COSV100887372; called by muse, mutect2, varscan2
- CSMD1 | c.9650G>T p.C3217F (on ENST00000520002; = p.C3216F on NM_033225.6) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100143098; called by muse, mutect2, varscan2
- CSMD1 | c.7984G>T p.E2662* (on ENST00000520002; = p.E2661* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 111/332 reads (33%) | catalogued as COSV100143102; called by muse, mutect2, varscan2
- CSMD3 | c.4362C>A p.S1454R (on ENST00000297405 / NM_001363185.1; = p.S1350R on NM_052900.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV99823518; called by muse, mutect2, varscan2
- CUBN | c.7628T>A p.M2543K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771607684, COSV100912020; called by muse, mutect2, varscan2
- CYP2B6 | c.1049A>T p.E350V | Missense Mutation (SNP) | VAF 72/136 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100137272, COSV57843514; called by muse, mutect2, varscan2
- DACH2 | c.1666G>A p.G556S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.478); catalogued as rs780040421, COSV100912454; called by muse, mutect2, varscan2
- DACT1 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV100241563; called by muse, mutect2, varscan2
- DCAF4 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 78/467 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100610878; called by muse, mutect2, varscan2
- DDX42 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100834823; called by muse, mutect2, varscan2
- DLC1 | c.1145C>G p.T382R | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV99360785; called by muse, mutect2, varscan2
- DLC1 | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); catalogued as COSV52290934; called by muse, mutect2, varscan2
- DLEC1 | c.4417G>A p.D1473N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as COSV100341388; called by muse, mutect2, varscan2
- DLGAP2 | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.328); catalogued as rs773355695, COSV101421011, COSV70099049; called by muse, mutect2, varscan2
- DMBX1 | c.910T>C p.Y304H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100760652; called by muse, mutect2, varscan2
- DNAH11 | c.2383C>A p.Q795K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as COSV100176781; called by muse, mutect2, varscan2
- DNAH11 | c.6152C>A p.T2051K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as COSV100176783; called by muse, mutect2, varscan2
- DNAH9 | c.10801C>G p.L3601V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV52349187, COSV99303811; called by muse, mutect2, varscan2
- DNAI3 | c.464C>G p.P155R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99641291; called by muse, mutect2, varscan2
- DPPA2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs773427525, COSV101524730; called by muse, mutect2, varscan2
- DPRX | c.234T>A p.H78Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100934044, COSV64949570; called by muse, mutect2, varscan2
- DSEL | c.1456A>G p.T486A | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100025214; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2328G>C p.Q776H | Missense Mutation (SNP) | VAF 116/224 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as COSV100668352; called by muse, mutect2, varscan2
- EIF4H | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99733241; called by muse, mutect2, varscan2
- ENDOU | c.396C>A p.S132R (on ENST00000422538 / NM_001172439.2; = p.S91R on NM_006025.4) | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99968175; called by muse, mutect2, varscan2
- ENPP1 | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100719366; called by muse, mutect2, varscan2
- ESRRG | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100752207, COSV100753411; called by muse, mutect2, varscan2
- FAM107B | c.67C>A p.P23T (on ENST00000378458 / NM_001320737.1; = p.P198T on NM_031453.3) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51693526, COSV99473459, COSV99473495; called by muse, mutect2, varscan2
- FAM160A2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV56410239; called by muse, mutect2, varscan2
- FANCA | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV101224659; called by muse, mutect2, varscan2
- FCGBP | c.10163T>C p.L3388P | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1323265475; called by muse, mutect2, varscan2
- FCRL2 | c.896G>C p.R299P | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV100829811; called by muse, mutect2
- FGF6 | c.241G>T p.G81W | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99960130; called by muse, mutect2, varscan2
- FGFR4 | c.2199G>T p.R733S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800552; called by mutect2, varscan2
- FIGN | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.19); catalogued as COSV100291423; called by muse, mutect2, varscan2
- FLG2 | c.3340G>T p.G1114C | Missense Mutation (SNP) | VAF 258/524 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV66167252; called by muse, mutect2, varscan2
- FRMPD1 | c.3799C>A p.P1267T | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.748); catalogued as COSV100899260; called by muse, mutect2, varscan2
- GABRA2 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100733769, COSV62919438; called by muse, mutect2
- GARRE1 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 106/541 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV55104761; called by muse, mutect2, varscan2
- GDPD3 | c.574-2A>G p.X192_splice | Splice Site (SNP) | VAF 74/171 reads (43%) | catalogued as COSV99531220; called by muse, mutect2, varscan2
- GFRA1 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.356); catalogued as COSV100815407; called by muse, mutect2
- GIGYF1 | c.1832C>A p.A611E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.113); catalogued as rs1484275719, COSV51943120, COSV99308710; called by muse, mutect2, varscan2
- GPR152 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs780147374, COSV100351408; called by muse, varscan2
- GRHL1 | c.1078T>G p.S360A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100257481; called by muse, mutect2, varscan2
- GRID1 | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.995); catalogued as COSV100021698, COSV100025077; called by muse, mutect2, varscan2
- H2BC15 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.493); catalogued as COSV57585904; called by muse, mutect2, varscan2
- HEATR1 | c.3811G>C p.G1271R | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV100857372; called by muse, mutect2, varscan2
- HERPUD2 | c.495A>G p.G165= | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100257785; called by muse, mutect2, varscan2
- HIVEP2 | c.5467G>A p.D1823N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50051527; called by muse, mutect2, varscan2
- HMCN1 | c.2229G>C p.R743S | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV99623669; called by muse, mutect2, varscan2
- ICE2 | c.2327A>G p.E776G | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99831255; called by muse, mutect2, varscan2
- IFNA17 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV101303435; called by muse, mutect2
- IGF2R | c.6694T>C p.C2232R | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100806825; called by muse, mutect2, varscan2
- IL21R | c.1454T>A p.L485Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100559791; called by muse, mutect2, varscan2
- IL27RA | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV99651890; called by muse, mutect2, varscan2
- IMPG1 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100885920; called by muse, mutect2, varscan2
- INSM1 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100044558; called by muse, mutect2, varscan2
- ITGAX | c.1884A>G p.I628M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1368140593, COSV99191418; called by muse, mutect2
- ITIH5 | c.2514C>A p.C838* | Nonsense Mutation (SNP) | VAF 19/144 reads (13%) | catalogued as COSV53659712, COSV99903597; called by muse, mutect2, varscan2
- JPH2 | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100881576, COSV65901973; called by muse, mutect2, varscan2
- KAT7 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV99371575; called by muse, mutect2
- KCNB1 | c.2556C>A p.S852R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100870371; called by muse, mutect2, varscan2
- KCNH8 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100108293; called by muse, mutect2, varscan2
- KCNJ3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99715178, COSV99715818; called by muse, mutect2, varscan2
- KCNJ4 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.075); catalogued as rs771447217, COSV100340983, COSV57856373; called by muse, mutect2
- KCNK10 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.034); catalogued as COSV100067259, COSV56648722; called by muse, mutect2, varscan2
- KCNT2 | c.720T>G p.F240L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); catalogued as COSV99651268; called by muse, mutect2, varscan2
- KDM5A | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV101238590; called by muse, mutect2, varscan2
- KDR | c.3320C>A p.P1107H | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816639; called by muse, mutect2, varscan2
- KIAA0408 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.794); catalogued as COSV100846757; called by muse, mutect2, varscan2
- KRT10 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1284338985, COSV54091764; called by muse, mutect2, varscan2
- KRT17 | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100245038; called by muse, mutect2, varscan2
- KRTAP10-3 | c.215C>G p.T72S | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100551749; called by muse, mutect2, varscan2
- LAMA1 | c.4470-1G>A p.X1490_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101054853, COSV67531708; called by muse, varscan2
- LAMB1 | c.1954A>T p.N652Y | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99739771; called by muse, mutect2, varscan2
- LCOR | c.4088T>G p.V1363G | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616555; called by muse, mutect2, varscan2
- LHCGR | c.1346C>A p.A449E | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV99683103; called by muse, mutect2, varscan2
- LIG4 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100799678; called by muse, mutect2, varscan2
- LILRB1 | c.641C>A p.S214Y (on ENST00000427581; = p.S178Y on NM_006669.6) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.318); catalogued as COSV100206851; called by muse, mutect2, varscan2
- LONP2 | c.1157G>T p.R386I | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99588794; called by muse, mutect2, varscan2
- LPL | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as CM155115, COSV100255257; called by muse, mutect2, varscan2
- LRRC7 | c.2882T>A p.I961N (on ENST00000651989 / NM_001370785.2; = p.I928N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99224256; called by muse, mutect2, varscan2
- LTA4H | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as COSV99956879; called by muse, mutect2, varscan2
- MAJIN | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1171112540, COSV100104115; called by muse, mutect2, varscan2
- MAML1 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV99482859; called by muse, mutect2, varscan2
- MAP3K20 | c.1870T>C p.Y624H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV100919379; called by muse, mutect2
- MARK2 | c.1169C>A p.S390Y | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100158021; called by muse, mutect2, varscan2
- MED12L | c.5034G>T p.E1678D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99851394; called by muse, mutect2, varscan2
- MGAM | c.1262G>T p.R421M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV101527361; called by muse, mutect2
- MMS22L | c.1085A>T p.Y362F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs773955486, COSV99246014; called by muse, mutect2, varscan2
- MSH4 | c.1230G>T p.T410= | Splice Region (SNP) | VAF 21/65 reads (32%) | catalogued as COSV54199753; called by muse, mutect2, varscan2
- MTARC1 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV100856236; called by muse, mutect2, varscan2
- MUC21 | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 246/571 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100888816; called by muse, mutect2, varscan2
- MYBPC1 | c.1874C>A p.A625E (on ENST00000550270 / NM_206820.2; = p.A650E on NM_002465.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100637725; called by muse, mutect2, varscan2
- MYO1D | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.184); catalogued as rs760738580, COSV100531913; called by muse, mutect2, varscan2
- MYO5C | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99954015; called by muse, mutect2, varscan2
- MYPN | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV100589492; called by muse, mutect2, varscan2
- NAV3 | c.5100C>A p.N1700K | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.328); catalogued as COSV99886638; called by muse, mutect2, varscan2
- NCAM2 | c.1419T>A p.Y473* | Nonsense Mutation (SNP) | VAF 73/233 reads (31%) | catalogued as COSV99520914; called by muse, mutect2, varscan2
- NDNF | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV101113087; called by muse, mutect2, varscan2
- NDST4 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52115462, COSV52120354; called by muse, mutect2
- NELL1 | c.1981-1G>T p.X661_splice | Splice Site (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100118679, COSV54295508; called by muse, mutect2, varscan2
- NELL2 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100418607; called by muse, mutect2, varscan2
- NFXL1 | c.2159G>T p.R720L | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100216540; called by muse, mutect2, varscan2
- NMS | c.390G>T p.W130C | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.579); catalogued as COSV100966541; called by muse, mutect2, varscan2
- NMS | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 39/197 reads (20%) | catalogued as COSV100966542, COSV65259381; called by muse, mutect2, varscan2
- NOL11 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99474810; called by muse, mutect2, varscan2
- NPAP1 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.414); catalogued as COSV100274729; called by muse, mutect2, varscan2
- NPY5R | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100642630; called by muse, mutect2, varscan2
- NR1H4 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99499966; called by muse, mutect2, varscan2
- NRDE2 | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583237; called by muse, mutect2, varscan2
- NT5C3A | c.641T>G p.V214G (on ENST00000610140 / NM_001374335.1; = p.V180G on NM_016489.13) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99640892; called by muse, mutect2, varscan2
- NUMA1 | c.2059G>C p.A687P | Missense Mutation (SNP) | VAF 95/191 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.466); catalogued as COSV100705743; called by muse, mutect2, varscan2
- OPALIN | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.354); catalogued as COSV100959565; called by muse, mutect2, varscan2
- OR2F1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101231282; called by muse, mutect2, varscan2
- OR2T3 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs374584382; called by muse, mutect2, varscan2
- OR4C3 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs147395616; called by muse, mutect2, varscan2
- OR4S2 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 74/120 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV100412538; called by muse, mutect2, varscan2
- OR51G1 | c.100T>C p.C34R | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1338060940, COSV100429116; called by muse, mutect2, varscan2
- OR5D14 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100162085; called by muse, mutect2, varscan2
- OR6T1 | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV100189714, COSV58308535; called by muse, mutect2, varscan2
- OR8H3 | c.870T>G p.Y290* | Nonsense Mutation (SNP) | VAF 33/205 reads (16%) | catalogued as COSV100538724; called by muse, mutect2, varscan2
- PANX3 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV52513815, COSV99421153; called by muse, mutect2, varscan2
- PAPPA | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV100072763; called by muse, mutect2, varscan2
- PAX7 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV64748651; called by muse, mutect2, varscan2
- PCDH1 | c.2410G>T p.G804C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99745442; called by muse, mutect2, varscan2
- PCDH10 | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99992886; called by muse, mutect2, varscan2
- PCDHA3 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as COSV100973537; called by muse, mutect2, varscan2
- PCNT | c.6427A>C p.K2143Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100855015; called by muse, mutect2, varscan2
- PDCD2L | c.850A>T p.T284S | Missense Mutation (SNP) | VAF 171/332 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99874846; called by muse, mutect2, varscan2
- PDE1B | c.437T>G p.V146G | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV99672099; called by muse, mutect2, varscan2
- PDZD2 | c.4631C>A p.T1544K | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); catalogued as COSV56853138; called by muse, mutect2, varscan2
- PGLYRP2 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99483741; called by muse, mutect2, varscan2
- PHF21B | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV100503463, COSV57559322; called by muse, mutect2, varscan2
- PHPT1 | c.147G>T p.W49C | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs992281551, COSV99915366; called by muse, mutect2, varscan2
- PIGN | c.2130G>T p.L710F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100715458; called by muse, mutect2, varscan2
- PIK3CG | c.1269G>T p.L423F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63249120, COSV63249445; called by muse, mutect2
- PKD1L1 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as rs867135875, COSV99218270; called by muse, mutect2, varscan2
- PKD2L1 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100559281; called by muse, mutect2, varscan2
- PLAA | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 96/156 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101263478; called by muse, mutect2, varscan2
- PLD5 | c.1605C>G p.N535K (on ENST00000442594; = p.N473K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100138693; called by muse, mutect2, varscan2
- PLD5 | c.326G>A p.R109Q (on ENST00000442594; = p.R47Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs749531675, COSV59160757; called by muse, mutect2
- PLXNA4 | c.3131G>T p.R1044L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV100322302; called by muse, mutect2, varscan2
- PLXNC1 | c.3884C>A p.S1295* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99312381; called by muse, mutect2, varscan2
- POLR2F | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.276); catalogued as rs774038371, COSV100704017; called by muse, mutect2, varscan2
- PPP1R9A | c.1357G>C p.A453P | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs945223046, COSV99194563; called by muse, mutect2
- PREX1 | c.4587A>G p.I1529M | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100906050; called by muse, mutect2, varscan2
- PRPF39 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs765240472, COSV100865954; called by muse, mutect2, varscan2
- PRXL2A | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100939744; called by muse, mutect2, varscan2
- PSG2 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 114/508 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV100283333; called by muse, mutect2, varscan2
- PSG6 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 71/376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779978213, COSV99413497; called by muse, mutect2, varscan2
- PTCRA | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485694; called by muse, mutect2, varscan2
- RASGEF1C | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100745516; called by muse, mutect2, varscan2
- RAVER1 | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as COSV99532302; called by muse, mutect2, varscan2
- RNF112 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101518330, COSV101518345; called by muse, mutect2, varscan2
- RNF182 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV101337837; called by muse, mutect2, varscan2
- RNF8 | c.764G>T p.R255M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100009338; called by muse, varscan2
- RSPH1 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769151189, COSV52321218; called by muse, mutect2, varscan2
- RYR3 | c.1603T>C p.C535R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211931; called by muse, mutect2, varscan2
- S1PR3 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100822450; called by muse, mutect2, varscan2
- SAMD7 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 36/718 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100156723; called by muse, mutect2
- SBSN | c.1562G>T p.G521V (on ENST00000452271 / NM_001166034.2; = p.G178V on NM_198538.4) | Missense Mutation (SNP) | VAF 191/361 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1161364552, COSV101510031; called by muse, mutect2, varscan2
- SCN10A | c.2989G>T p.V997L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101479229; called by muse, mutect2, varscan2
- SCN5A | c.4438T>A p.L1480I (on ENST00000333535 / NM_198056.3; = p.L1479I on NM_000335.5) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100345846, COSV100346329, COSV61141698; called by muse, mutect2, varscan2
- SEC31B | c.2228G>A p.R743K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100947198; called by muse, mutect2, varscan2
- SEL1L2 | c.86G>T p.R29I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV99532510; called by muse, mutect2, varscan2
- SEMA3A | c.634A>T p.R212W | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99545122; called by muse, mutect2, varscan2
- SEMA3C | c.783G>T p.M261I | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV99542304; called by muse, mutect2, varscan2
- SEMA3E | c.1485G>C p.E495D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100317158; called by muse, varscan2
- SEMA4C | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100560715, COSV100560878; called by muse, mutect2, varscan2
- SGCE | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99722104; called by muse, mutect2
- SIGLEC12 | c.810C>A p.A270= (on ENST00000291707 / NM_053003.4; = p.A152= on NM_033329.2) | Splice Region (SNP) | VAF 21/61 reads (34%) | catalogued as COSV99389022; called by muse, mutect2, varscan2
- SLC13A4 | c.1616T>A p.L539Q | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100818781; called by muse, mutect2, varscan2
- SLC19A3 | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV51452319, COSV99295615; called by muse, mutect2, varscan2
- SLC2A14 | c.1058C>A p.A353E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100533492; called by mutect2, varscan2
- SLC35F4 | c.1535C>A p.A512D (on ENST00000339762 / NM_001352015.2; = p.A476D on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV100333503; called by muse, mutect2, varscan2
- SLC6A12 | c.349+1G>A p.X117_splice | Splice Site (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100674981; called by muse, mutect2, varscan2
- SLC6A6 | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV100691857; called by muse, mutect2, varscan2
- SLC7A2 | c.566G>A p.W189* (on ENST00000494857 / NM_001370338.1; = p.W229* on NM_003046.6) | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | catalogued as COSV99134302; called by muse, mutect2, varscan2
- SLCO1C1 | c.1357G>T p.A453S | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99858426; called by muse, mutect2, varscan2
- SLCO2B1 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99214227; called by muse, mutect2, varscan2
- SNTG2 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100421339, COSV57983004; called by muse, mutect2, varscan2
- SORBS2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53010478; called by muse, mutect2, varscan2
- SPEG | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs766708598, COSV56681235; called by mutect2, varscan2
- SPINT1 | c.203C>G p.S68W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688861, COSV59801391; called by muse, mutect2, varscan2
- SPTA1 | c.5069A>G p.N1690S | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750345614, COSV100934163; called by muse, mutect2, varscan2
- SPTA1 | c.3933G>A p.M1311I | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63756528; called by muse, mutect2
- SPTA1 | c.2564G>A p.R855K | Missense Mutation (SNP) | VAF 21/339 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV63757615; called by muse, mutect2
- STON1-GTF2A1L | c.3529A>G p.I1177V | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.437); catalogued as rs763623640, COSV100561431; called by muse, mutect2, varscan2
- STX16 | c.457C>G p.Q153E (on ENST00000371141 / NM_001001433.3; = p.Q132E on NM_003763.6) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV100397182; called by muse, mutect2
- SULT1C4 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV99731454; called by muse, mutect2, varscan2
- SYT5 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100845847; called by muse, mutect2, varscan2
- TASOR2 | c.1754A>T p.H585L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100049928; called by muse, mutect2, varscan2
- TATDN3 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100875174; called by muse, mutect2, varscan2
- TDRD6 | c.2557G>T p.D853Y | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100287059; called by muse, mutect2, varscan2
- TDRD9 | c.1379T>A p.V460D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100174597, COSV59157022; called by muse, mutect2, varscan2
- TENT4A | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs138124674; called by muse, varscan2
- TET3 | c.3837C>G p.Y1279* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV101327575; called by muse, mutect2, varscan2
- TEX35 | c.326A>T p.Q109L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV99273975; called by muse, mutect2, varscan2
- TGM6 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99171671; called by muse, mutect2, varscan2
- TGM7 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV101476815; called by muse, mutect2, varscan2
- THEMIS | c.1758G>A p.K586= | Splice Region (SNP) | VAF 61/214 reads (29%) | catalogued as COSV100965239; called by muse, mutect2, varscan2
- THOC2 | c.699A>C p.E233D | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs770539761, COSV55546473, COSV99832667; called by muse, mutect2, varscan2
- THSD7B | c.1722C>T p.R574= | Splice Region (SNP) | VAF 15/50 reads (30%) | catalogued as rs762458222, COSV55698987; called by muse, mutect2, varscan2
- TLE4 | c.584A>T p.H195L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99511049; called by muse, mutect2, varscan2
- TMIGD2 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV100010101; called by muse, mutect2
- TNN | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV53429565; called by muse, mutect2, varscan2
- TNR | c.2545G>T p.G849C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99687333; called by muse, mutect2, varscan2
- TNRC18 | c.5470G>A p.D1824N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV101269525; called by muse, mutect2, varscan2
- TP53BP1 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 100/365 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55499424, COSV55511772; called by muse, mutect2, varscan2
- TPD52L2 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.093); catalogued as COSV99410508; called by muse, mutect2, varscan2
- TRIM48 | c.551G>C p.W184S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101338173; called by muse, mutect2, varscan2
- TRIM49 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV61670310; called by mutect2, varscan2
- TRUB1 | c.1043C>G p.T348R | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV100075909; called by muse, mutect2, varscan2
- TTN | c.87374G>A p.W29125* (on ENST00000591111; = p.W21701* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 34/165 reads (21%) | catalogued as COSV60342149; called by muse, mutect2, varscan2
- TTN | c.81700G>C p.A27234P (on ENST00000591111; = p.A19810P on NM_003319.4) | Missense Mutation (SNP) | VAF 37/105 reads (35%) | PolyPhen possibly damaging (0.572); catalogued as COSV100592799; called by muse, mutect2, varscan2
- TTN | c.70270C>A p.H23424N (on ENST00000591111; = p.H16000N on NM_003319.4) | Missense Mutation (SNP) | VAF 84/281 reads (30%) | PolyPhen benign (0.006); catalogued as rs1318351282, COSV100592800; called by muse, mutect2, varscan2
- TTN | c.44295G>T p.K14765N (on ENST00000591111; = p.K7341N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | PolyPhen probably damaging (0.997); catalogued as COSV100592811, COSV59989776; called by muse, mutect2, varscan2
- TTN | c.19043A>G p.E6348G (on ENST00000591111; = p.E5421G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | PolyPhen probably damaging (0.997); catalogued as COSV100592816; called by muse, mutect2
- UBE2E3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs774720190, COSV101150604, COSV66585347; called by muse, mutect2, varscan2
- UHRF2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.41); catalogued as COSV99436089; called by muse, mutect2, varscan2
- UNC45A | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as COSV100376526; called by muse, mutect2, varscan2
- UNC93A | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 101/465 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100023017, COSV100023243; called by muse, mutect2, varscan2
- USH2A | c.13277A>G p.N4426S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV100228461; called by muse, mutect2, varscan2
- WWC2 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.071); catalogued as rs752532710, COSV100968129, COSV66715052; called by muse, mutect2, varscan2
- XIRP2 | c.8770C>A p.H2924N (on ENST00000628543; = p.H3099N on NM_152381.6) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV99738022; called by muse, mutect2, varscan2
- ZBED9 | c.516G>T p.M172I | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV101509090; called by muse, mutect2, varscan2
- ZEB2 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100354907; called by muse, mutect2, varscan2
- ZFAND6 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99928376; called by muse, mutect2, varscan2
- ZFYVE28 | c.2138G>T p.R713I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99342358; called by muse, varscan2
- ZNF280A | c.1316T>C p.M439T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV100130942; called by muse, mutect2, varscan2
- ZNF471 | c.1876C>A p.P626T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100340343; called by muse, mutect2, varscan2
- ZNF483 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100492627; called by muse, mutect2, varscan2
- ZNF512B | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as COSV99411217; called by muse, mutect2, varscan2
- ZNF85 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100059441; called by muse, mutect2, varscan2
- ZNF99 | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV101233678; called by muse, mutect2, varscan2
- ZUP1 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.315); catalogued as COSV100884977; called by muse, mutect2, varscan2
- ABLIM3 | c.613dup p.Q205Pfs*5 | Frame Shift Ins (INS) | VAF 52/156 reads (33%) | called by mutect2, pindel, varscan2
- ETV1 | c.1405del p.H469Tfs*47 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- GPC1 | c.1613del p.P538Rfs*15 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- LRBA | c.6498del p.F2167Sfs*7 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- MCM10 | c.588_595+11del p.X196_splice (on ENST00000484800 / NM_182751.3; = p.X195_splice on NM_018518.5) | Splice Site (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- MDGA2 | c.1869del p.R624Efs*5 (on ENST00000399232 / NM_001113498.2; = p.R326Efs*5 on NM_182830.4) | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- MKRN2 | c.309A>T p.E103D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.225); called by muse, mutect2
- NMT2 | c.952del p.R318Efs*3 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- PDZRN3 | c.2606dup p.H870Afs*142 | Frame Shift Ins (INS) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- RNF8 | c.798dup p.H267Tfs*2 | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | called by pindel, varscan2
- SETD5 | c.2495del p.K832Rfs*8 | Frame Shift Del (DEL) | VAF 46/226 reads (20%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3878G>A p.S1293N | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by mutect2, varscan2
- TTN | c.101074del p.Q33692Sfs*72 (on ENST00000591111; = p.Q26268Sfs*72 on NM_003319.4) | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- ABCB4 | c.756A>G p.A252= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV99709652, COSV99711559; called by muse, mutect2, varscan2
- AC136428.1 | c.309C>T p.N103= | Silent (SNP) | VAF 119/466 reads (26%) | catalogued as rs748789189, COSV101434938, COSV101434974; called by muse, mutect2, varscan2
- ACCSL | c.1200T>G p.S400= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV101122147; called by muse, mutect2, varscan2
- ADGRL3 | c.3595C>A p.R1199= (on ENST00000506720 / NM_001322402.2; = p.R1131= on NM_015236.6) | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV72230748, COSV72232434; called by muse, mutect2, varscan2
- AGAP6 | c.801A>G p.L267= (on ENST00000374056 / NM_001365867.1; = p.L290= on NM_001077665.2) | Silent (SNP) | VAF 185/497 reads (37%) | catalogued as COSV100929030; called by muse, mutect2, varscan2
- AHNAK | c.14985A>G p.S4995= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV99945410; called by muse, mutect2, varscan2
- ALOX12B | c.844C>A p.R282= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV100046607; called by muse, mutect2, varscan2
- ANK2 | c.6795C>T p.T2265= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99999427; called by muse, mutect2, varscan2
- APOC2 | c.60C>G p.V20= | Silent (SNP) | VAF 28/424 reads (7%) | catalogued as COSV99376891; called by muse, mutect2
- ARHGEF15 | c.270C>T p.S90= | Silent (SNP) | VAF 144/324 reads (44%) | catalogued as rs751012549, COSV100729970; called by muse, mutect2, varscan2
- CAV1 | c.357C>T p.F119= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs201302545, COSV61952547; called by muse, mutect2, varscan2
- CCDC102B | c.894G>A p.K298= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100102022; called by muse, mutect2, varscan2
- CCPG1 | c.1026G>A p.G342= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100196903; called by muse, mutect2
- CDC42BPA | c.2052A>G p.Q684= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs1011648716, COSV100503612; called by muse, mutect2, varscan2
- CHD1 | c.1863T>C p.N621= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV99399047; called by muse, mutect2, varscan2
- COL17A1 | c.171G>A p.L57= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100793024; called by muse, mutect2, varscan2
- COL4A4 | c.1380T>C p.C460= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100306114; called by muse, mutect2, varscan2
- COL5A3 | c.3534T>A p.G1178= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99318163; called by muse, mutect2, varscan2
- CORO1C | c.1212G>C p.V404= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99775689; called by muse, mutect2, varscan2
- CSMD3 | c.4317G>T p.L1439= (on ENST00000297405 / NM_001363185.1; = p.L1335= on NM_052900.3) | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99823524; called by muse, mutect2, varscan2
- DDC | c.903C>G p.P301= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100779106; called by muse, mutect2, varscan2
- DLGAP4 | c.2472G>A p.Q824= (on ENST00000339266 / NM_001365621.1; = p.Q821= on NM_014902.6) | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100210774; called by muse, mutect2, varscan2
- DMD | c.3048G>C p.R1016= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV100817650; called by muse, mutect2, varscan2
- DPP10 | c.2235T>A p.A745= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV100058083; called by muse, mutect2, varscan2
- E2F7 | c.684G>A p.E228= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as COSV100523276; called by muse, mutect2, varscan2
- EFCAB5 | c.3075C>G p.L1025= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV100299744; called by muse, mutect2, varscan2
- FCN2 | c.639C>A p.A213= | Silent (SNP) | VAF 103/264 reads (39%) | catalogued as COSV99391069; called by muse, mutect2, varscan2
- FER1L6 | c.1335T>C p.D445= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV101205400; called by muse, mutect2, varscan2
- FLCN | c.72G>C p.V24= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99550058; called by muse, mutect2, varscan2
- GABBR2 | c.192C>A p.L64= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99409053; called by muse, mutect2, varscan2
- GPR31 | c.576C>T p.L192= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV100834098; called by muse, mutect2
- GPR37 | c.1383C>T p.C461= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs746041839, COSV100390512; called by muse, mutect2, varscan2
- HOXB5 | c.660C>A p.T220= | Silent (SNP) | VAF 44/184 reads (24%) | catalogued as COSV99494348; called by muse, mutect2
- HS2ST1 | c.69G>T p.A23= | Silent (SNP) | VAF 49/103 reads (48%) | catalogued as COSV100085813; called by muse, mutect2, varscan2
- IGHG1 | c.642C>A p.P214= | Silent (SNP) | VAF 128/418 reads (31%) | called by muse, mutect2, varscan2
- IGHV3-20 | c.258A>T p.R86= | Silent (SNP) | VAF 126/355 reads (35%) | catalogued as rs371464615; called by muse, mutect2, varscan2
- IGHV4-39 | c.231G>T p.G77= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs762967894; called by muse, mutect2, varscan2
- IGKV1D-13 | c.136C>A p.R46= | Silent (SNP) | VAF 36/208 reads (17%) | catalogued as rs376818855; called by muse, mutect2, varscan2
- IQCA1 | c.1770C>A p.T590= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV99608472; called by muse, mutect2, varscan2
- KIAA1549L | c.5445C>T p.D1815= (on ENST00000321505; = p.D2112= on NM_012194.3) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs760336987, COSV58594350; called by muse, mutect2, varscan2
- KIAA1958 | c.1929C>A p.P643= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100515808; called by muse, mutect2, varscan2
- KYNU | c.564G>T p.R188= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV51590404; called by muse, mutect2, varscan2
- LCT | c.1284G>T p.V428= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99928485; called by muse, mutect2, varscan2
- LHX5 | c.201C>T p.C67= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs1424763506, COSV99922361; called by muse, mutect2, varscan2
- LINS1 | c.1650T>G p.S550= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100129929; called by muse, mutect2, varscan2
- MCM3AP | c.198T>C p.H66= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99386423; called by muse, mutect2, varscan2
- MMS22L | c.3057G>A p.L1019= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99246011; called by muse, mutect2, varscan2
- MRGPRX3 | c.135C>T p.N45= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs566088854, COSV101283480; called by muse, mutect2, varscan2
- MYOM2 | c.2047C>A p.R683= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV100036536; called by muse, mutect2, varscan2
- NELL2 | c.1773G>T p.G591= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as COSV100418605, COSV61585632; called by muse, mutect2, varscan2
- NHLH2 | c.310C>T p.L104= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100204868; called by muse, mutect2, varscan2
- NIBAN1 | c.1098T>A p.R366= | Silent (SNP) | VAF 73/239 reads (31%) | catalogued as COSV100836186; called by muse, mutect2, varscan2
- OR2T3 | c.6C>T p.C2= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV100613040; called by muse, mutect2, varscan2
- OR2T6 | c.231T>C p.I77= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100861476; called by muse, mutect2, varscan2
- OR4D5 | c.810C>A p.A270= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100189713, COSV58306193; called by muse, mutect2, varscan2
- OR4F15 | c.402C>A p.T134= | Silent (SNP) | VAF 63/306 reads (21%) | catalogued as COSV100173811; called by muse, mutect2, varscan2
- OR4S2 | c.18C>T p.N6= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1281742838, COSV56745922, COSV56748516; called by muse, mutect2
- OR5AN1 | c.495T>C p.L165= | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as COSV100004275; called by muse, mutect2, varscan2
- OR5D14 | c.717C>A p.A239= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV100162087, COSV100162417, COSV59455247; called by muse, mutect2, varscan2
- PCDH18 | c.3264C>A p.A1088= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100787002; called by muse, mutect2, varscan2
- PHRF1 | c.240G>T p.G80= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99199420; called by muse, mutect2, varscan2
- PLXND1 | c.726C>T p.S242= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100138958; called by muse, mutect2, varscan2
- PRAMEF17 | c.81C>T p.I27= | Silent (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- PRDM9 | c.2190C>T p.S730= | Silent (SNP) | VAF 92/184 reads (50%) | catalogued as COSV57005210, COSV99689720; called by muse, varscan2
- RALGAPA1 | c.5619C>T p.T1873= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV99353097; called by muse, mutect2, varscan2
- RGS7 | c.1092G>T p.L364= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV100464310; called by muse, mutect2, varscan2
- RNF17 | c.1011C>T p.Y337= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs141654694; called by muse, mutect2, varscan2
- RP1 | c.432C>T p.V144= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs777144010, COSV55120315; called by muse, mutect2, varscan2
- SALL3 | c.3501C>T p.N1167= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs376239776, COSV101610085; called by muse, mutect2, varscan2
- SCN10A | c.1134G>T p.V378= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV101479230; called by muse, mutect2, varscan2
- SCN11A | c.3474G>C p.L1158= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as COSV100180831; called by muse, mutect2, varscan2
- SEMA6D | c.2322T>G p.P774= (on ENST00000316364 / NM_153618.2; = p.P712= on NM_020858.2) | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100316375; called by muse, mutect2, varscan2
- SHROOM2 | c.3561G>C p.L1187= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV101098113; called by muse, mutect2, varscan2
- SLC9A5 | c.2487C>A p.L829= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV100237015; called by muse, mutect2, varscan2
- SOX5 | c.1134G>A p.K378= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV58648985; called by muse, mutect2, varscan2
- SYNE1 | c.8947T>C p.L2983= (on ENST00000367255 / NM_182961.4; = p.L2990= on NM_033071.3) | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as COSV99552024; called by muse, mutect2, varscan2
- SYNE1 | c.6132A>G p.Q2044= (on ENST00000367255 / NM_182961.4; = p.Q2051= on NM_033071.3) | Silent (SNP) | VAF 56/186 reads (30%) | catalogued as COSV99552026; called by muse, mutect2, varscan2
- SYT1 | c.1221C>T p.T407= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99693518; called by muse, mutect2
- TAAR1 | c.660G>A p.Q220= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99257450; called by muse, mutect2, varscan2
- TAF3 | c.948G>A p.K316= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100719797; called by muse, mutect2, varscan2
- TAS2R39 | c.612C>A p.I204= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs747826962, COSV101489389; called by muse, mutect2, varscan2
- TNFRSF10D | c.969T>C p.A323= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100441556; called by muse, mutect2, varscan2
- TPSAB1 | c.144G>A p.L48= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100126751; called by muse, mutect2, varscan2
- TRBV5-1 | c.318C>A p.A106= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.45160C>A p.R15054= (on ENST00000591111; = p.R7630= on NM_003319.4) | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs751502842, COSV100592805, COSV59935923; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH2A | c.10404C>T p.P3468= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100228463; called by muse, mutect2
- USH2A | c.9537C>A p.I3179= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as COSV100228466, COSV56321766; called by muse, mutect2, varscan2
- WDR91 | c.2187C>G p.L729= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100615539; called by muse, mutect2, varscan2
- ZNF443 | c.1815A>T p.G605= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100041891; called by muse, mutect2, varscan2
- AC244258.1 | n.390G>T | RNA (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- ALDH3A1 | chr17:19748379 C>A | 5'Flank (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99855719, COSV99856043; called by muse, mutect2, varscan2
- DSCR4 | n.197C>T | RNA (SNP) | VAF 17/54 reads (31%) | catalogued as rs762650963, COSV100077003; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+606del | Intron (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- RPL31P57 | n.204C>G | RNA (SNP) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- SYTL2 | c.1459+1823G>T | Intron (SNP) | VAF 54/297 reads (18%) | catalogued as COSV100313602; called by muse, mutect2, varscan2
